Somatic mutation profile of tumor specimen TCGA-RP-A690-06A (aliquot TCGA-RP-A690-06A-11D-A30X-08) from TCGA case TCGA-RP-A690, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 66.9 years (24,450 days).
Specimen TCGA-RP-A690-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57f4454e-eb8f-4075-98d9-0832487366b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RP-A690-10A (Blood Derived Normal), aliquot TCGA-RP-A690-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/043e984e-1b97-424e-9aef-b92519b026c5

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Nonsense Mutation 2, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 20/42 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 21/46 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519961, COSV59205431, COSV59206122, COSV59206364; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRG3 | c.1457T>G p.V486G | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs753225768, COSV100342529; called by muse, mutect2, varscan2
- AMELX | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 61/121 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.797); catalogued as COSV100498653, COSV61635587; called by muse, mutect2, varscan2
- EXPH5 | c.1402C>T p.R468* | Nonsense Mutation (SNP) | VAF 48/118 reads (41%) | catalogued as rs370254735; called by muse, mutect2, varscan2
- HBS1L | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370235823, COSV63200128; called by muse, mutect2
- NEUROG2 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.023); catalogued as rs1384268695, COSV100511844, COSV99046275; called by muse, mutect2, varscan2
- NUDT22 | c.506A>C p.Q169P | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99655957; called by muse, mutect2, varscan2
- PEAK1 | c.1963G>C p.E655Q | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.368); catalogued as COSV56933184; called by muse, varscan2
- TEAD4 | c.39G>A p.W13* | Nonsense Mutation (SNP) | VAF 38/77 reads (49%) | catalogued as COSV100622114; called by muse, mutect2, varscan2
- TG | c.8237C>T p.T2746M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as rs181114893, COSV99602125; called by muse, mutect2, varscan2
- TGM1 | c.2035G>A p.V679M | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs765258731, COSV99253137; called by muse, mutect2, varscan2
- ETAA1 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PEAK1 | c.1969del p.T657Pfs*4 | Frame Shift Del (DEL) | VAF 28/100 reads (28%) | called by pindel, varscan2
- OR9I1 | c.472C>T p.L158= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV100110253; called by muse, mutect2, varscan2
- RNF123 | c.402A>G p.K134= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as COSV100570952; called by muse, mutect2, varscan2
- STAP1 | c.39G>A p.R13= | Silent (SNP) | VAF 43/88 reads (49%) | catalogued as COSV55331035, COSV99609555; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73821059 T>G | 3'Flank (SNP) | VAF 22/32 reads (69%) | called by muse, mutect2, varscan2
